Somatic mutation profile of tumor specimen MP2PRT-PATUDT-TMP1-A (aliquot MP2PRT-PATUDT-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PATUDT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,758 days).
Specimen MP2PRT-PATUDT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 486ab589-e1f6-4dac-960f-29b91c0cc442.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATUDT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATUDT-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df438c1a-fcf1-4296-bbcb-d48be5379b03

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC22A6 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 18/510 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1452359474; called by muse, mutect2
- UNC45B | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767706635; called by muse, mutect2, varscan2
- CPSF4L | c.420C>G p.Y140* | Nonsense Mutation (SNP) | VAF 9/292 reads (3%) | called by muse, mutect2
- GYPA | c.336C>T p.Y112= | Silent (SNP) | VAF 26/209 reads (12%) | catalogued as rs140442202; called by muse, varscan2
